Gene-level copy-number profile of tumor specimen ALCH-B4CB-TTP1-A from ALCHEMIST case ALCH-B4CB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.8 years (28,065 days).
Specimen ALCH-B4CB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ac03490b-16c3-410d-8309-5543087c5d71.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4CB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/5da905b3-4395-4312-86a6-061054522da5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 2,476; copy number 2: 52,219; copy number 3: 3,116; copy number 4: 251; copy number 5: 142; copy number 6: 85; copy number 7: 2; copy number 8: 38; copy number 12: 2; copy number 15: 1; copy number 18: 1.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:49,873,347–49,903,873, 3 genes (within-gene range 0–2): ACTBP13, MST1R, AC105935.2.
- chr3:52,228,612–52,246,788, 2 genes (within-gene range 0–2): TWF2, AC006252.1.
- chr4:84,544,304–84,544,519, 1 gene: RPL3P13.
- chr6:168,053,166–168,101,511, 1 gene: FRMD1.
- chr7:98,214,624–98,252,232, 1 gene: TECPR1.
- chr7:129,770,383–129,785,185, 4 genes: MIR182, MIR96, MIR183, AC084864.1.
- chr14:105,248,490–105,251,093, 1 gene (within-gene range 0–2): BTBD6.
- chr15:25,184,306–25,225,284, 23 genes (within-gene range 0–2): SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:25,232,387–25,250,940, 11 genes (within-gene range 0–2): SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:76,174,891–76,181,486, 1 gene (within-gene range 0–2): AC091100.1.
- chr15:90,855,935–90,883,458, 2 genes: RN7SL363P, FURIN.
- chr16:56,351,886–56,353,524, 1 gene (within-gene range 0–2): AC009102.2.
- chr17:80,200,673–80,220,923, 2 genes (within-gene range 0–2): AC087741.1, SGSH.
- chr19:2,754,715–2,783,362, 1 gene: SGTA.
- chr20:34,955,810–35,002,437, 3 genes (within-gene range 0–2): MYH7B, MIR499A, MIR499B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 271 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,175,181–242,175,634, 1 gene, copy number 5: RPL23AP88.
- chr5:58,198–58,915, 1 gene, copy number 6: AC113430.1.
- chr5:612,340–5,490,220, 90 genes, copy number 5–8 (broad region; genes not listed).
- chr5:36,485,343–39,889,059, 56 genes, copy number 5: RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1.
- chr8:64,091–264,703, 12 genes, copy number 6 (within-gene range 2–6): AC144568.1, AC144568.2, AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3.
- chr11:747,415–784,297, 5 genes, copy number 5: TALDO1, GATD1, AP006621.3, AP006621.5, AP006621.2.
- chr11:1,947,278–1,989,920, 2 genes, copy number 12–15: MRPL23, MRPL23-AS1.
- chr14:57,999,735–58,298,139, 1 gene, copy number 5 (within-gene range 4–5): ARMH4.
- chr14:58,141,279–59,184,247, 24 genes, copy number 5 (within-gene range 3–5): UBA52P3, RN7SL598P, AL121579.1, ACTR10, PSMA3, AL132989.1, PSMA3-AS1, HMGB1P14, LINC00216, RNU6-341P, ARID4A, AL139021.2, TOMM20L, AL139021.1, TIMM9, KIAA0586, Y_RNA, HSBP1P1, HNRNPCP1, RPL9P5, DACT1, LINC01500, AL049873.1, AL049873.2.
- chr14:62,069,518–64,601,644, 51 genes, copy number 6: AL390816.1, AL390816.2, LINC00643, LINC00644, AL390816.3, AL389895.1, ATP5F1AP4, KCNH5, AL137191.1, PARP1P2, RHOJ, AL049871.1, GPHB5, PPP2R5E, AL132992.1, AL136038.3, AL136038.1, GCATP1, WDR89, AL136038.2, HSPE1P2, RNU6-597P, Y_RNA, RNU6-1162P, AL136038.4, U3, SGPP1, EIF2S2P1, RNU7-116P, SYNE2, AL161670.1, RPS28P1, Y_RNA, ESR2, MIR548H1, AL161756.1, TEX21P, AL161756.3, AL161756.2, MTHFD1, AL122035.1, AL122035.2, ZBTB25, AKAP5, ZBTB1, AL049869.2, AL049869.3, HSPA2, PPP1R36, AL049869.1, NUP50P1.
- chr14:104,677,694–105,065,445, 21 genes, copy number 6: MIR4710, INF2, AL583722.3, ADSS1, SIVA1, AL583722.1, AKT1, ZBTB42, AL590326.1, LINC00638, RPS26P49, RPS2P4, AL583810.2, AL583810.1, CEP170B, AL583810.3, PLD4, AHNAK2, CLBA1, CDCA4, GPR132.
- chr14:105,583,731–105,588,395, 1 gene, copy number 12: IGHA2.
- chr17:83,132,647–83,240,804, 4 genes, copy number 5–7: AC139099.3, AC139099.2, AC139099.1, RPL23AP87.
- chr21:43,446,601–43,479,534, 2 genes, copy number 5–18 (within-gene range 3–18): LINC00319, LINC00313.

Autosomal genes at a single copy (total copy number 1): 2,476. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
